TCGA case TCGA-EE-A29S — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5dec1b6a-5d60-463c-9655-fc7ed79ca19d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 79 years; Vital status: Dead; Days to death: 1,864 days (5.1 years).

Diagnoses (11)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: Progression; Age at diagnosis: 83.5 years (30,484 days); Days to diagnosis: 1,397 days (3.8 years); Prior treatment: No; Days to last follow up: 1,864 days (5.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Extremities; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >2.0-4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 79.6 years (29,087 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
4. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 83.5 years (30,505 days); Days to diagnosis: 1,418 days (3.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,418 days (3.9 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
5. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Abdomen, NOS. Age at diagnosis: 84.2 years (30,759 days); Days to diagnosis: 1,672 days (4.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,672 days (4.6 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
6. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Liver. Age at diagnosis: 84.3 years (30,774 days); Days to diagnosis: 1,687 days (4.6 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
7. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Thorax, NOS. Age at diagnosis: 84.3 years (30,774 days); Days to diagnosis: 1,687 days (4.6 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
8. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 84.3 years (30,787 days); Days to diagnosis: 1,700 days (4.7 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
9. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Pancreas, NOS. Age at diagnosis: 84.3 years (30,787 days); Days to diagnosis: 1,700 days (4.7 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
10. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Bone, NOS. Age at diagnosis: 84.3 years (30,787 days); Days to diagnosis: 1,700 days (4.7 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
11. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lower limb, NOS. Age at diagnosis: 84.3 years (30,787 days); Days to diagnosis: 1,700 days (4.7 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (10 entries)
- Day 1,418 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,418 days (3.9 years).
- Day 1,672 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 1,672 days (4.6 years).
- Day 1,687 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 1,687 days (4.6 years).
- Day 1,687 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,687 days (4.6 years).
- Day 1,700 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 1,700 days (4.7 years).
- Day 1,700 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pancreas, NOS; Days to progression: 1,700 days (4.7 years).
- Day 1,700 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lower limb, NOS; Days to progression: 1,700 days (4.7 years).
- Day 1,700 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,700 days (4.7 years).
- Days to follow up: 1,701 days (4.7 years); Disease response: With Tumor.
- Days to follow up: 1,864 days (5.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A29S-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A29S-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 250 mg.
  Slide TCGA-EE-A29S-06A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EE-A29S-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 2.5; Primary melanoma tumor ulceration: No; Primary melanoma mitotic rate: 7; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,864 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,864 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,418 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A29S-06A-11D-A191-01): tumor purity 0.69, ploidy 1.91, whole-genome doublings 0.
